Somatic mutation profile of tumor specimen C3N-02289-06 (aliquot CPT0186180006) from CPTAC case C3N-02289, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 73.7 years (26,931 days).
Specimen C3N-02289-06: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f5934f79-78f3-4f64-90f2-832f6a94061d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02289-31 (Blood Derived Normal), aliquot CPT0186960002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/964b21d7-3d4d-4b79-9399-6f1cf34148bd

The open-access MAF lists 294 somatic variants for this specimen: 202 protein-altering or splice-affecting, 58 silent, 34 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 187, Silent 58, Intron 20, Nonsense Mutation 6, 3'UTR 6, Splice Site 3, Frame Shift Del 3, RNA 3, 5'Flank 2, Splice Region 2, 5'UTR 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR2 | c.1150G>A p.G384R | Missense Mutation (SNP) | VAF 274/681 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs1554927408, CM960654, COSV60640087, COSV60649627; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.638G>T p.R213L | Missense Mutation (SNP) | VAF 54/402 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs587778720, CM004906, CM022474, COSV52665093, COSV52668963, COSV52693072; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACP7 | c.751C>T p.H251Y | Missense Mutation (SNP) | VAF 35/470 reads (7%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as COSV100488391; called by muse, mutect2
- ACVR1 | c.1507G>T p.D503Y | Missense Mutation (SNP) | VAF 38/341 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV55116258; called by muse, mutect2, varscan2
- C2CD3 | c.5407G>A p.A1803T | Missense Mutation (SNP) | VAF 49/337 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.031); catalogued as rs1230933651; called by muse, mutect2, varscan2
- CDC16 | c.223C>T p.L75F | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.936); catalogued as COSV52958054; called by muse, mutect2
- CDH10 | c.2179G>T p.A727S | Missense Mutation (SNP) | VAF 34/223 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs763581492, COSV52589090, COSV52594161; called by muse, mutect2, varscan2
- CDH18 | c.1589G>T p.R530L | Missense Mutation (SNP) | VAF 19/149 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs764611303, COSV56925874; called by muse, mutect2, varscan2
- CDR2 | c.1204G>A p.G402S | Missense Mutation (SNP) | VAF 15/212 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs563641354; called by muse, mutect2
- CEP170B | c.3850A>G p.T1284A (on ENST00000453495; = p.T1213A on NM_015005.3) | Missense Mutation (SNP) | VAF 39/359 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.908); catalogued as rs371039114; called by muse, mutect2
- CNGB3 | c.2061T>A p.S687R | Missense Mutation (SNP) | VAF 38/508 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.184); catalogued as rs1162402050; called by muse, mutect2
- CXXC1 | c.1498C>T p.R500C | Missense Mutation (SNP) | VAF 17/244 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53276526; called by muse, mutect2
- CYP2A13 | c.1302C>T p.I434= | Splice Region (SNP) | VAF 46/662 reads (7%) | catalogued as rs779688987, COSV57837380; called by muse, mutect2
- DYSF | c.733G>A p.A245T | Missense Mutation (SNP) | VAF 30/348 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.86); catalogued as rs770518944; called by muse, mutect2
- EVI5 | c.1471A>G p.I491V | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.019); catalogued as rs1365214969, COSV64831093; called by muse, mutect2
- FAT4 | c.14015G>A p.S4672N | Missense Mutation (SNP) | VAF 28/239 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.167); catalogued as rs772782057, COSV100629333; called by muse, mutect2, varscan2
- FMN2 | c.2278G>T p.V760L | Missense Mutation (SNP) | VAF 17/262 reads (6%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.023); catalogued as COSV100146991; called by muse, mutect2
- GFY | c.1082G>T p.R361L | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs1047490380; called by muse, mutect2
- KCNA4 | c.411G>T p.E137D | Missense Mutation (SNP) | VAF 22/300 reads (7%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs780472651, COSV60255752; called by muse, mutect2
- KCNJ16 | c.578G>C p.R193T | Missense Mutation (SNP) | VAF 10/281 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV52254137, COSV52256853; called by muse, mutect2
- LRP1B | c.10471G>T p.D3491Y | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.98); catalogued as COSV67185308, COSV67189813; called by muse, mutect2
- MAGEC1 | c.1829A>G p.Y610C | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.782); catalogued as rs759242025; called by muse, mutect2, varscan2
- MBD5 | c.3772A>G p.K1258E | Missense Mutation (SNP) | VAF 33/247 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.99); catalogued as rs1258991767; called by muse, mutect2, varscan2
- MDH1B | c.1363C>G p.L455V | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.636); catalogued as rs762979183; called by muse, mutect2, varscan2
- MMP10 | c.1313C>T p.A438V | Missense Mutation (SNP) | VAF 25/218 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1338156020; called by muse, mutect2, varscan2
- MYF5 | c.662G>C p.G221A | Missense Mutation (SNP) | VAF 28/315 reads (9%) | SIFT tolerated (0.98); PolyPhen benign (0.001); catalogued as COSV57356320; called by muse, mutect2
- NAALAD2 | c.217C>A p.L73M | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.722); catalogued as COSV100427986; called by muse, mutect2
- NAV3 | c.3542C>A p.P1181Q | Missense Mutation (SNP) | VAF 36/362 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV57067616, COSV99031155; called by muse, mutect2
- NCKAP5 | c.4444G>C p.E1482Q | Missense Mutation (SNP) | VAF 26/324 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58425191; called by muse, mutect2
- NHLRC1 | c.313C>A p.R105S | Missense Mutation (SNP) | VAF 24/416 reads (6%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as rs909097062, COSV100513595; called by muse, mutect2
- NLGN1 | c.2109G>T p.K703N | Missense Mutation (SNP) | VAF 15/142 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV64344778; called by muse, mutect2, varscan2
- OLFML2B | c.626G>A p.R209Q | Missense Mutation (SNP) | VAF 11/138 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs778489676, COSV54195295; called by muse, mutect2
- OR2AT4 | c.242C>A p.T81N | Missense Mutation (SNP) | VAF 28/459 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.828); catalogued as rs748282068, COSV100532415; called by muse, mutect2
- OR2G3 | c.257A>G p.Q86R | Missense Mutation (SNP) | VAF 15/263 reads (6%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs1313314239; called by muse, mutect2
- OR52I2 | c.565C>A p.L189M | Missense Mutation (SNP) | VAF 28/376 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.888); catalogued as rs1394056837; called by muse, mutect2
- OR5T1 | c.811T>C p.Y271H | Missense Mutation (SNP) | VAF 15/171 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as rs746985420; called by muse, mutect2
- OR6N2 | c.590T>C p.L197P | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1353167240; called by muse, mutect2, varscan2
- OR8U1 | c.196C>G p.L66V | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV100163694; called by muse, mutect2
- P2RY10 | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs920221122; called by muse, mutect2, varscan2
- PCDH15 | c.3559C>A p.P1187T | Missense Mutation (SNP) | VAF 34/267 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1203212360, COSV100222583, COSV57265301; called by mutect2, varscan2
- PCDHB7 | c.107C>T p.A36V | Missense Mutation (SNP) | VAF 31/290 reads (11%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.407); catalogued as rs782066223, COSV50758250; called by muse, mutect2, varscan2
- PIK3CG | c.2450G>T p.C817F | Missense Mutation (SNP) | VAF 18/224 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.042); catalogued as COSV63245462; called by muse, mutect2
- PPP4C | c.16G>T p.D6Y | Missense Mutation (SNP) | VAF 18/268 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as rs1373739135; called by muse, mutect2
- RELN | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 29/447 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0.196); catalogued as rs760337154, COSV59033800, COSV59037109; called by muse, mutect2
- SAXO1 | c.968G>T p.R323L | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.897); catalogued as COSV65868657; called by muse, mutect2, varscan2
- SIN3A | c.3640G>T p.V1214L | Missense Mutation (SNP) | VAF 29/180 reads (16%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as rs750796375; called by muse, mutect2, varscan2
- SLC22A8 | c.362T>C p.L121P | Missense Mutation (SNP) | VAF 21/289 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as rs752560586; called by muse, mutect2
- SLC6A5 | c.461T>C p.M154T | Missense Mutation (SNP) | VAF 21/346 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as rs1401298957; called by muse, mutect2
- SMARCD1 | c.874-1G>T p.X292_splice | Splice Site (SNP) | VAF 14/94 reads (15%) | catalogued as COSV67413288; called by muse, mutect2
- SPANXN1 | c.155T>C p.L52S | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs1556883081; called by muse, mutect2, varscan2
- SPINT1 | c.1505C>T p.P502L (on ENST00000344051 / NM_181642.3; = p.P486L on NM_003710.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/345 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.36); catalogued as rs755087916, COSV59802382; called by muse, mutect2
- SRMS | c.143C>T p.P48L | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.058); catalogued as rs1569019540, COSV53920053, COSV53922683; called by muse, mutect2
- TNS1 | c.1697G>T p.R566L | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as rs752348651; called by muse, mutect2, varscan2
- TNXB | c.9679G>A p.D3227N (on ENST00000647633; = p.D2980N on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/586 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.301); catalogued as rs750418889, COSV100926687; called by muse, mutect2
- TRPM6 | c.1321G>T p.E441* | Nonsense Mutation (SNP) | VAF 12/335 reads (4%) | catalogued as COSV62510707; called by muse, mutect2
- TTLL6 | c.2194C>T p.P732S (on ENST00000393382 / NM_001130918.3; = p.P425S on NM_173623.3) | Missense Mutation (SNP) | VAF 46/242 reads (19%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.06); catalogued as rs748667239; called by muse, mutect2, varscan2
- UGT3A1 | c.1483C>A p.L495I | Missense Mutation (SNP) | VAF 23/402 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.034); catalogued as COSV57101326, COSV99955474; called by muse, mutect2
- ZFHX4 | c.749C>A p.S250Y | Missense Mutation (SNP) | VAF 15/185 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51495622; called by muse, mutect2
- ZNF573 | c.1427G>T p.G476V (on ENST00000536220 / NM_001172692.1; = p.G418V on NM_152360.3) | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100265876; called by muse, mutect2, varscan2
- ZNF716 | c.192G>T p.L64F | Missense Mutation (SNP) | VAF 26/298 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.272); catalogued as COSV101348493, COSV70781171; called by muse, mutect2
- ZNF804B | c.1831C>T p.Q611* | Nonsense Mutation (SNP) | VAF 12/162 reads (7%) | catalogued as COSV100306255; called by muse, mutect2
- ZNF865 | c.2930G>A p.R977H | Missense Mutation (SNP) | VAF 38/289 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as COSV57595997; called by muse, mutect2, varscan2
- A2M | c.3371C>T p.A1124V | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AFM | c.1522C>A p.P508T | Missense Mutation (SNP) | VAF 35/284 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- AKAP12 | c.2233G>T p.E745* | Nonsense Mutation (SNP) | VAF 13/206 reads (6%) | called by muse, mutect2
- AKR7A3 | c.431A>G p.N144S | Missense Mutation (SNP) | VAF 22/462 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- ANO5 | c.2378C>T p.T793I | Missense Mutation (SNP) | VAF 19/221 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.371); called by muse, mutect2
- AP001781.2 | c.175A>G p.I59V | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); called by muse, mutect2
- AP3B1 | c.978A>G p.I326M | Missense Mutation (SNP) | VAF 29/212 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- ASIC5 | c.155A>C p.N52T | Missense Mutation (SNP) | VAF 39/254 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- ASPH | c.1012G>C p.D338H | Missense Mutation (SNP) | VAF 11/146 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ATP2B2 | c.2565G>T p.M855I (on ENST00000352432; = p.M821I on NM_001683.5) | Missense Mutation (SNP) | VAF 30/271 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- BDH1 | c.869G>T p.S290I | Missense Mutation (SNP) | VAF 39/327 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- BMP10 | c.1082C>A p.A361E | Missense Mutation (SNP) | VAF 15/222 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); called by muse, mutect2
- C10orf67 | c.552C>G p.F184L (on ENST00000636213 / NM_001365862.2; = p.F152L on NM_001351306.2) | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.241); called by muse, mutect2
- C3AR1 | c.720T>A p.D240E | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2
- CACNB2 | c.1319T>A p.I440N (on ENST00000324631 / NM_201596.3; = p.I385N on NM_000724.4) | Missense Mutation (SNP) | VAF 19/652 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- CACNG2 | c.652C>T p.L218F | Missense Mutation (SNP) | VAF 63/593 reads (11%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- CALHM2 | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 50/394 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CATSPERG | c.3424A>G p.M1142V | Missense Mutation (SNP) | VAF 32/266 reads (12%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- CAVIN2 | c.656C>T p.A219V | Missense Mutation (SNP) | VAF 33/294 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CBR4 | c.384del p.S129Lfs*5 | Frame Shift Del (DEL) | VAF 11/99 reads (11%) | called by mutect2, pindel, varscan2
- CCDC78 | c.637G>A p.V213M | Missense Mutation (SNP) | VAF 36/282 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- CCN2 | c.219del p.C74Afs*121 | Frame Shift Del (DEL) | VAF 28/300 reads (9%) | called by mutect2, pindel
- CDH22 | c.1829C>T p.S610F | Missense Mutation (SNP) | VAF 50/514 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.823); called by muse, mutect2
- CENPJ | c.1340A>C p.K447T | Missense Mutation (SNP) | VAF 13/145 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.038); called by muse, mutect2
- CEP83 | c.296C>G p.T99S | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- CERS6 | c.466A>G p.T156A | Missense Mutation (SNP) | VAF 20/288 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.034); called by muse, mutect2
- CLIP3 | c.1544C>A p.T515K | Missense Mutation (SNP) | VAF 29/454 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.08); called by muse, mutect2
- COL6A3 | c.3229A>G p.R1077G | Missense Mutation (SNP) | VAF 10/236 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.185); called by muse, mutect2
- COL9A1 | c.754T>C p.C252R | Missense Mutation (SNP) | VAF 40/572 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- CPEB1 | c.1849A>T p.M617L (on ENST00000617958; = p.M552L on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/256 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); called by muse, mutect2
- CRYBG3 | c.3082T>A p.F1028I | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.349); called by muse, mutect2
- CTLA4 | c.316A>G p.T106A | Missense Mutation (SNP) | VAF 15/403 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.018); called by muse, mutect2
- DCST1 | c.1195T>A p.Y399N | Missense Mutation (SNP) | VAF 27/294 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- DLGAP3 | c.814G>T p.G272C | Missense Mutation (SNP) | VAF 14/209 reads (7%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.892); called by muse, mutect2
- DNAH7 | c.6034G>C p.A2012P | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- DPP6 | c.754C>A p.Q252K (on ENST00000377770 / NM_001364500.2; = p.Q190K on NM_001936.5) | Missense Mutation (SNP) | VAF 12/244 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2
- DYNC2H1 | c.11345T>G p.L3782* | Nonsense Mutation (SNP) | VAF 8/160 reads (5%) | called by muse, mutect2
- DYSF | c.595G>T p.G199W | Missense Mutation (SNP) | VAF 68/651 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- EDEM1 | c.1102G>T p.G368W | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EHMT1 | c.37G>T p.G13W | Missense Mutation (SNP) | VAF 26/268 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.514); called by muse, mutect2
- F13A1 | c.1030G>A p.D344N | Missense Mutation (SNP) | VAF 16/248 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FAM20C | c.877C>A p.Q293K | Missense Mutation (SNP) | VAF 12/268 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.495); called by muse, mutect2
- FAM47A | c.485C>G p.A162G | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- FLI1 | c.1066T>A p.Y356N | Missense Mutation (SNP) | VAF 39/471 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FRMD3 | c.541A>G p.K181E | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GIMAP4 | c.109G>T p.G37C | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GNB3 | c.204-2A>T p.X68_splice | Splice Site (SNP) | VAF 25/270 reads (9%) | called by muse, mutect2
- GNL2 | c.1495G>C p.G499R | Missense Mutation (SNP) | VAF 23/228 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.021); called by muse, mutect2
- GRM1 | c.1688A>G p.K563R | Missense Mutation (SNP) | VAF 36/450 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.09); called by muse, mutect2
- HDAC3 | c.997G>T p.A333S | Missense Mutation (SNP) | VAF 35/386 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.01); called by muse, mutect2
- HMCN1 | c.2941C>T p.P981S | Missense Mutation (SNP) | VAF 18/251 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HOOK3 | c.1620+3A>T | Splice Region (SNP) | VAF 9/146 reads (6%) | called by muse, mutect2
- HSPA12B | c.2000C>G p.T667S | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.84); PolyPhen benign (0.09); called by muse, varscan2
- IGBP1 | c.339A>T p.L113F | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.585); called by muse, mutect2, varscan2
- IGF1R | c.1806G>C p.L602F | Missense Mutation (SNP) | VAF 23/383 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.006); called by muse, mutect2
- KCNC3 | c.1070T>A p.V357D | Missense Mutation (SNP) | VAF 46/604 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- KCNH8 | c.417G>T p.K139N | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- KCNS1 | c.209G>A p.R70H | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- KCTD14 | c.625G>T p.D209Y | Missense Mutation (SNP) | VAF 158/601 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KIAA0100 | c.1718del p.K573Rfs*4 | Frame Shift Del (DEL) | VAF 24/216 reads (11%) | called by mutect2, pindel, varscan2
- KISS1R | c.97C>A p.P33T | Missense Mutation (SNP) | VAF 34/337 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- KIT | c.2823C>G p.N941K | Missense Mutation (SNP) | VAF 36/446 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.07); called by muse, mutect2
- LTBP1 | c.4540+1G>T p.X1514_splice (on ENST00000404816 / NM_206943.4; = p.X1188_splice on NM_000627.4) | Splice Site (SNP) | VAF 13/116 reads (11%) | called by muse, mutect2, varscan2
- MACC1 | c.995C>A p.T332N | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.312); called by muse, mutect2
- MAGEB4 | c.490C>A p.L164I | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- MARCO | c.767G>C p.G256A | Missense Mutation (SNP) | VAF 27/321 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MKI67 | c.4653C>G p.I1551M | Missense Mutation (SNP) | VAF 52/442 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- MMP10 | c.1312G>T p.A438S | Missense Mutation (SNP) | VAF 24/220 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MMP26 | c.26C>G p.T9S | Missense Mutation (SNP) | VAF 23/421 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.029); called by muse, mutect2
- MTR | c.1321A>G p.I441V | Missense Mutation (SNP) | VAF 30/372 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.172); called by muse, mutect2
- MUC4 | c.8768C>G p.T2923R | Missense Mutation (SNP) | VAF 35/1528 reads (2%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.517); called by muse, mutect2
- NCAPH2 | c.731G>A p.G244D | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.03); called by muse, mutect2
- NCEH1 | c.1142A>G p.Y381C (on ENST00000538775; = p.Y341C on NM_020792.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/254 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NLRP8 | c.1853A>G p.E618G | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- NPY1R | c.893A>C p.H298P | Missense Mutation (SNP) | VAF 12/125 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- NSG2 | c.258C>G p.I86M | Missense Mutation (SNP) | VAF 26/318 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2
- OR10G2 | c.752T>A p.I251N | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR56A3 | c.371A>G p.Y124C | Missense Mutation (SNP) | VAF 33/458 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); called by muse, mutect2
- OR5AP2 | c.230C>A p.A77D | Missense Mutation (SNP) | VAF 14/243 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.303); called by muse, mutect2
- OR5J2 | c.440G>T p.G147V | Missense Mutation (SNP) | VAF 18/163 reads (11%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- OSBPL5 | c.452C>G p.P151R | Missense Mutation (SNP) | VAF 24/419 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); called by muse, mutect2
- OSBPL5 | c.451C>G p.P151A | Missense Mutation (SNP) | VAF 24/412 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- PCYT1A | c.411G>T p.Q137H | Missense Mutation (SNP) | VAF 40/445 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); called by muse, mutect2
- PDE1C | c.2048A>G p.H683R | Missense Mutation (SNP) | VAF 11/169 reads (7%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.074); called by muse, mutect2
- PDPR | c.509A>G p.N170S | Missense Mutation (SNP) | VAF 30/770 reads (4%) | SIFT tolerated (0.59); PolyPhen benign (0.014); called by muse, mutect2
- PEX5L | c.746A>G p.H249R | Missense Mutation (SNP) | VAF 14/231 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2
- PGK2 | c.966G>T p.K322N | Missense Mutation (SNP) | VAF 26/362 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.071); called by muse, mutect2
- PHLDB1 | c.329T>A p.V110D | Missense Mutation (SNP) | VAF 18/164 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.332); called by muse, mutect2
- PLA2G4A | c.1046T>A p.F349Y | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PPIP5K1 | c.3881A>G p.D1294G (on ENST00000396923; = p.D1269G on NM_014659.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/544 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.014); called by muse, mutect2
- PPP4R3C | c.2458G>T p.D820Y | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- PRAMEF14 | c.1132C>T p.Q378* | Nonsense Mutation (SNP) | VAF 89/753 reads (12%) | called by muse, mutect2, varscan2
- PRR23A | c.33C>G p.F11L | Missense Mutation (SNP) | VAF 19/254 reads (7%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2
- PRRC2C | c.1550G>C p.R517P (on ENST00000367742; = p.R515P on NM_015172.4) | Missense Mutation (SNP) | VAF 16/181 reads (9%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.005); called by muse, mutect2
- PSMB11 | c.511C>A p.Q171K | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.087); called by muse, mutect2
- RASL12 | c.121C>A p.L41M | Missense Mutation (SNP) | VAF 13/244 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); called by muse, mutect2
- RBBP6 | c.274A>G p.T92A | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.344); called by mutect2, varscan2
- RIF1 | c.683T>G p.L228R | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RNF103 | c.1190C>G p.S397C | Missense Mutation (SNP) | VAF 15/157 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.993); called by muse, mutect2
- RPAIN | c.25C>A p.R9S | Missense Mutation (SNP) | VAF 47/375 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.693); called by muse, mutect2, varscan2
- RYR3 | c.3614C>A p.T1205K | Missense Mutation (SNP) | VAF 40/413 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2
- SCART1 | c.2231C>T p.P744L | Missense Mutation (SNP) | VAF 46/554 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.599); called by muse, mutect2
- SEMA6A | c.2589T>A p.S863R | Missense Mutation (SNP) | VAF 29/241 reads (12%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC25A23 | c.950G>C p.G317A | Missense Mutation (SNP) | VAF 25/253 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- SLC35C1 | c.654G>T p.K218N | Missense Mutation (SNP) | VAF 69/618 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SLC9A9 | c.548G>T p.G183V | Missense Mutation (SNP) | VAF 10/216 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.283); called by muse, mutect2
- SLC9A9 | c.547G>T p.G183C | Missense Mutation (SNP) | VAF 10/218 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2
- SMG5 | c.1762A>T p.S588C | Missense Mutation (SNP) | VAF 33/287 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- SPOCD1 | c.2209C>A p.H737N | Missense Mutation (SNP) | VAF 61/485 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SYNE1 | c.24593A>T p.E8198V (on ENST00000367255 / NM_182961.4; = p.E8127V on NM_033071.3) | Missense Mutation (SNP) | VAF 20/182 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SYNE1 | c.8441A>T p.Q2814L (on ENST00000367255 / NM_182961.4; = p.Q2821L on NM_033071.3) | Missense Mutation (SNP) | VAF 19/170 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.297); called by muse, varscan2
- SYNM | c.4640A>T p.K1547I (on ENST00000336292 / NM_145728.3; = p.K1235I on NM_015286.6) | Missense Mutation (SNP) | VAF 26/439 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TECPR2 | c.2288C>T p.P763L | Missense Mutation (SNP) | VAF 17/250 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.691); called by muse, mutect2
- TENM3 | c.2077G>T p.G693W | Missense Mutation (SNP) | VAF 26/163 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- THBS3 | c.198dup p.K67Qfs*53 | Frame Shift Ins (INS) | VAF 38/384 reads (10%) | called by mutect2, pindel
- TMC2 | c.165C>G p.S55R | Missense Mutation (SNP) | VAF 20/648 reads (3%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.137); called by muse, mutect2
- TNFAIP2 | c.163G>T p.G55C | Missense Mutation (SNP) | VAF 42/396 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- TOP3A | c.2097C>G p.S699R | Missense Mutation (SNP) | VAF 27/232 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- TRAV4 | c.327C>A p.D109E | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- TRPA1 | c.1476T>G p.N492K | Missense Mutation (SNP) | VAF 14/214 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2
- TRPM1 | c.652G>A p.G218S | Missense Mutation (SNP) | VAF 11/234 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); called by muse, mutect2
- TTC17 | c.2163A>C p.K721N | Missense Mutation (SNP) | VAF 20/159 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- TTC21B | c.1053G>C p.M351I | Missense Mutation (SNP) | VAF 15/186 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2
- TTC24 | c.970A>G p.S324G | Missense Mutation (SNP) | VAF 18/262 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2
- TTLL6 | c.2195C>T p.P732L (on ENST00000393382 / NM_001130918.3; = p.P425L on NM_173623.3) | Missense Mutation (SNP) | VAF 47/241 reads (20%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- TTN | c.29828C>G p.P9943R (on ENST00000591111; = p.P9016R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/75 reads (11%) | PolyPhen possibly damaging (0.531); called by muse, mutect2, varscan2
- TXNDC16 | c.820G>T p.V274F | Missense Mutation (SNP) | VAF 33/229 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- UBE3D | c.487A>C p.I163L | Missense Mutation (SNP) | VAF 24/300 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2
- USF3 | c.5672G>C p.S1891T | Missense Mutation (SNP) | VAF 15/217 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.393); called by muse, mutect2
- VTI1A | c.49G>T p.A17S | Missense Mutation (SNP) | VAF 84/303 reads (28%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- WASHC2A | c.1972G>T p.A658S | Missense Mutation (SNP) | VAF 60/543 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- WBP1 | c.309T>A p.H103Q | Missense Mutation (SNP) | VAF 25/191 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- WDR70 | c.523G>T p.E175* | Nonsense Mutation (SNP) | VAF 13/145 reads (9%) | called by muse, mutect2
- WNT8B | c.95G>T p.G32V | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZBTB37 | c.1425A>T p.Q475H | Missense Mutation (SNP) | VAF 60/365 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZFP28 | c.592C>G p.Q198E | Missense Mutation (SNP) | VAF 26/279 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2
- ZNF248 | c.1460C>T p.T487I | Missense Mutation (SNP) | VAF 9/182 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ZNF263 | c.163C>T p.P55S | Missense Mutation (SNP) | VAF 25/240 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- ZNF530 | c.1547A>T p.E516V | Missense Mutation (SNP) | VAF 27/282 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); called by muse, mutect2
- ZNF573 | c.1426G>T p.G476W (on ENST00000536220 / NM_001172692.1; = p.G418W on NM_152360.3) | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ASTN1 | c.3513G>A p.K1171= | Silent (SNP) | VAF 17/180 reads (9%) | called by muse, mutect2, varscan2
- BEND3 | c.1575C>T p.R525= | Silent (SNP) | VAF 26/320 reads (8%) | called by muse, mutect2
- CACNA2D2 | c.1365C>T p.I455= | Silent (SNP) | VAF 33/217 reads (15%) | catalogued as rs760989430, COSV99817526; ClinVar: likely benign; called by muse, mutect2, varscan2
- CALCA | c.126C>T p.L42= | Silent (SNP) | VAF 31/470 reads (7%) | catalogued as COSV59027996; called by muse, mutect2
- CD1A | c.837G>C p.R279= | Silent (SNP) | VAF 14/136 reads (10%) | catalogued as COSV99192286; called by mutect2, varscan2
- CELSR2 | c.7179C>T p.L2393= | Silent (SNP) | VAF 24/584 reads (4%) | called by muse, mutect2
- CHD6 | c.2376C>T p.L792= | Silent (SNP) | VAF 22/250 reads (9%) | called by muse, mutect2
- CORIN | c.2376C>A p.R792= | Silent (SNP) | VAF 13/173 reads (8%) | called by muse, mutect2
- DLL1 | c.1764G>A p.E588= | Silent (SNP) | VAF 36/520 reads (7%) | catalogued as rs752345957; called by muse, mutect2
- DNAH14 | c.10077T>C p.H3359= (on ENST00000445597; = p.H4367= on NM_001367479.1) | Silent (SNP) | VAF 30/350 reads (9%) | catalogued as rs560668546; called by muse, mutect2
- DPP6 | c.753C>A p.G251= (on ENST00000377770 / NM_001364500.2; = p.G189= on NM_001936.5) | Silent (SNP) | VAF 12/247 reads (5%) | called by muse, mutect2
- DRD2 | c.1320C>T p.I440= | Silent (SNP) | VAF 36/692 reads (5%) | called by muse, mutect2
- DSG2 | c.2046A>T p.V682= | Silent (SNP) | VAF 32/392 reads (8%) | called by muse, mutect2
- E2F7 | c.1134G>C p.L378= | Silent (SNP) | VAF 7/79 reads (9%) | called by muse, mutect2
- ECEL1 | c.459C>T p.I153= | Silent (SNP) | VAF 33/293 reads (11%) | catalogued as rs767982707, COSV58811493; called by muse, mutect2, varscan2
- ESPNL | c.1200C>A p.A400= | Silent (SNP) | VAF 49/257 reads (19%) | called by muse, mutect2, varscan2
- FRRS1 | c.1074A>G p.P358= | Silent (SNP) | VAF 28/216 reads (13%) | called by muse, mutect2, varscan2
- GALNT17 | c.201G>T p.L67= | Silent (SNP) | VAF 28/212 reads (13%) | called by muse, mutect2, varscan2
- GIP | c.237C>A p.A79= | Silent (SNP) | VAF 16/92 reads (17%) | called by muse, mutect2, varscan2
- GNAS | c.249G>T p.P83= | Silent (SNP) | VAF 46/546 reads (8%) | called by muse, mutect2
- GREB1 | c.3141C>T p.D1047= | Silent (SNP) | VAF 33/242 reads (14%) | called by muse, mutect2, varscan2
- HNRNPL | c.1377C>T p.I459= | Silent (SNP) | VAF 15/136 reads (11%) | called by muse, mutect2
- HOXD11 | c.633C>G p.G211= | Silent (SNP) | VAF 21/249 reads (8%) | catalogued as COSV50910389; called by muse, mutect2
- HYLS1 | c.453A>C p.S151= | Silent (SNP) | VAF 28/288 reads (10%) | called by muse, mutect2
- KIFC2 | c.315G>C p.P105= | Silent (SNP) | VAF 16/156 reads (10%) | called by muse, mutect2, varscan2
- LGI4 | c.1461C>G p.L487= | Silent (SNP) | VAF 18/163 reads (11%) | called by muse, mutect2, varscan2
- LRRK2 | c.3972G>A p.Q1324= | Silent (SNP) | VAF 14/98 reads (14%) | catalogued as COSV100111404; called by muse, mutect2, varscan2
- MAP1A | c.25C>A p.R9= | Silent (SNP) | VAF 19/219 reads (9%) | called by muse, mutect2
- MINAR1 | c.546C>T p.S182= | Silent (SNP) | VAF 12/216 reads (6%) | called by muse, mutect2
- MUC6 | c.1467C>T p.V489= | Silent (SNP) | VAF 11/137 reads (8%) | catalogued as rs775625262; called by muse, mutect2
- MYO15B | c.3429G>T p.P1143= | Silent (SNP) | VAF 18/182 reads (10%) | called by muse, mutect2, varscan2
- NEB | c.11409G>A p.E3803= | Silent (SNP) | VAF 30/342 reads (9%) | called by muse, mutect2
- NLGN3 | c.540C>T p.G180= (on ENST00000358741 / NM_181303.2; = p.G160= on NM_018977.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/282 reads (6%) | catalogued as COSV62443613; called by muse, mutect2
- NPHS1 | c.516C>A p.T172= | Silent (SNP) | VAF 38/322 reads (12%) | catalogued as CD087053, COSV100800100; called by mutect2, varscan2
- NUP37 | c.135C>T p.V45= | Silent (SNP) | VAF 16/83 reads (19%) | called by muse, mutect2
- OR2T3 | c.639C>A p.L213= | Silent (SNP) | VAF 24/166 reads (14%) | catalogued as COSV62082886; called by muse, varscan2
- OR4S2 | c.735C>G p.V245= | Silent (SNP) | VAF 14/98 reads (14%) | catalogued as rs147882026, COSV100412531, COSV56746644; called by muse, mutect2, varscan2
- OR5AP2 | c.231C>A p.A77= | Silent (SNP) | VAF 14/246 reads (6%) | called by muse, mutect2
- OXR1 | c.1266T>A p.I422= (on ENST00000442977 / NM_001198532.1; = p.I421= on NM_018002.3) | Silent (SNP) | VAF 15/150 reads (10%) | called by muse, mutect2
- PCDHA4 | c.1452G>A p.A484= | Silent (SNP) | VAF 83/711 reads (12%) | catalogued as rs782266582, COSV100793514, COSV63542602; called by muse, mutect2, varscan2
- PEAK1 | c.3915C>T p.C1305= | Silent (SNP) | VAF 30/391 reads (8%) | catalogued as rs757277454, COSV56932771; called by muse, mutect2
- RARA | c.981G>A p.G327= | Silent (SNP) | VAF 51/340 reads (15%) | catalogued as rs777589328; called by muse, mutect2, varscan2
- RFX4 | c.1779C>T p.P593= (on ENST00000392842 / NM_213594.3; = p.P499= on NM_032491.6) | Silent (SNP) | VAF 15/128 reads (12%) | called by muse, mutect2, varscan2
- SAMD9L | c.3846T>C p.Y1282= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as rs1391625449; called by muse, mutect2, varscan2
- SOX18 | c.1093C>T p.L365= | Silent (SNP) | VAF 24/392 reads (6%) | called by muse, mutect2
- SPTA1 | c.3120G>C p.P1040= | Silent (SNP) | VAF 44/385 reads (11%) | catalogued as rs200809766; called by muse, mutect2, varscan2
- SURF6 | c.957G>A p.Q319= | Silent (SNP) | VAF 48/428 reads (11%) | catalogued as rs1248467216; called by muse, mutect2, varscan2
- TOPAZ1 | c.477G>A p.K159= | Silent (SNP) | VAF 8/100 reads (8%) | called by muse, mutect2
- TRAPPC9 | c.3171C>T p.P1057= | Silent (SNP) | VAF 59/521 reads (11%) | called by muse, mutect2, varscan2
- TRPV5 | c.246G>T p.A82= | Silent (SNP) | VAF 29/244 reads (12%) | catalogued as COSV99520188; called by muse, mutect2, varscan2
- TSPAN4 | c.156G>T p.S52= | Silent (SNP) | VAF 29/321 reads (9%) | called by muse, mutect2
- TTC24 | c.582C>A p.A194= | Silent (SNP) | VAF 8/78 reads (10%) | called by muse, mutect2, varscan2
- TTC24 | c.583C>T p.L195= | Silent (SNP) | VAF 9/79 reads (11%) | called by muse, mutect2, varscan2
- TTN | c.34110T>C p.P11370= (on ENST00000591111; = p.P10443= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/88 reads (9%) | called by muse, mutect2
- XIRP2 | c.2289A>G p.E763= (on ENST00000628543; = p.E938= on NM_152381.6) | Silent (SNP) | VAF 6/73 reads (8%) | called by muse, mutect2
- ZFHX4 | c.1158G>A p.A386= | Silent (SNP) | VAF 15/140 reads (11%) | catalogued as rs1314056291, COSV99256949; called by muse, mutect2, varscan2
- ZFHX4 | c.1575C>T p.S525= | Silent (SNP) | VAF 13/136 reads (10%) | catalogued as rs537094874; called by muse, mutect2, varscan2
- ZFPM2 | c.1569G>T p.L523= | Silent (SNP) | VAF 43/504 reads (9%) | called by muse, mutect2
- AC100868.1 | c.152-2087A>C | Intron (SNP) | VAF 32/324 reads (10%) | called by muse, mutect2
- AC100868.1 | c.152-2088C>A | Intron (SNP) | VAF 31/319 reads (10%) | called by muse, mutect2
- AC106741.1 | c.*26C>A | 3'UTR (SNP) | VAF 21/208 reads (10%) | called by muse, mutect2, varscan2
- ACAN | c.2026+109T>C | Intron (SNP) | VAF 24/203 reads (12%) | called by muse, mutect2, varscan2
- ADAMTS8 | c.-77G>A | 5'UTR (SNP) | VAF 15/144 reads (10%) | catalogued as rs1369936469; called by muse, mutect2, varscan2
- AK7 | c.1754-12T>A | Intron (SNP) | VAF 20/131 reads (15%) | called by muse, mutect2, varscan2
- ANKRD11 | c.7470+368C>T | Intron (SNP) | VAF 11/136 reads (8%) | called by muse, mutect2
- ARHGAP20 | c.*2252C>T | 3'UTR (SNP) | VAF 12/78 reads (15%) | called by muse, mutect2, varscan2
- BTN2A2 | c.*1353G>T | 3'UTR (SNP) | VAF 8/126 reads (6%) | called by muse, mutect2
- CCT5 | chr5:10250267 G>A | 5'Flank (SNP) | VAF 35/260 reads (13%) | called by muse, mutect2, varscan2
- CHMP6 | chr17:81004330 T>C | 3'Flank (SNP) | VAF 6/32 reads (19%) | catalogued as rs1379098409; called by muse, mutect2
- DAPK2 | c.858+15A>G | Intron (SNP) | VAF 8/170 reads (5%) | called by muse, mutect2
- DERA | c.750+74A>T | Intron (SNP) | VAF 9/58 reads (16%) | called by muse, mutect2
- DNAI2 | c.1347+82G>C | Intron (SNP) | VAF 75/586 reads (13%) | called by muse, mutect2, varscan2
- FAM189A2 | c.857-214A>G | Intron (SNP) | VAF 6/59 reads (10%) | called by muse, mutect2
- FBXL18 | c.*8C>A | 3'UTR (SNP) | VAF 5/26 reads (19%) | called by muse, mutect2, varscan2
- GVINP1 | n.4838C>A | RNA (SNP) | VAF 14/158 reads (9%) | called by muse, mutect2
- IGFN1 | c.1242-1878G>T | Intron (SNP) | VAF 26/246 reads (11%) | called by muse, mutect2
- LAMP5 | c.64+14T>A | Intron (SNP) | VAF 20/185 reads (11%) | called by muse, mutect2, varscan2
- NAV3 | c.6519-225G>A | Intron (SNP) | VAF 12/82 reads (15%) | called by muse, mutect2
- PLEKHM1P1 | n.618A>C | RNA (SNP) | VAF 73/490 reads (15%) | called by muse, mutect2, varscan2
- PWWP2A | c.584+10232G>A | Intron (SNP) | VAF 20/187 reads (11%) | called by muse, mutect2
- RABGEF1 | c.635-492G>T | Intron (SNP) | VAF 16/197 reads (8%) | catalogued as rs954707341; called by muse, mutect2
- SLC22A20P | n.1518G>A | RNA (SNP) | VAF 45/540 reads (8%) | catalogued as rs1411874853; called by muse, mutect2
- SLPI | c.*38G>T | 3'UTR (SNP) | VAF 8/173 reads (5%) | called by muse, mutect2
- SPATA31C1 | n.523-70C>T | Intron (SNP) | VAF 26/566 reads (5%) | catalogued as rs1228799703; called by muse, mutect2
- SSH1 | c.111-13635A>T | Intron (SNP) | VAF 19/137 reads (14%) | catalogued as COSV58468331; called by muse, mutect2, varscan2
- ST6GAL1 | c.706-8269A>T | Intron (SNP) | VAF 20/444 reads (5%) | called by muse, mutect2
- TMEM17 | c.318+36T>C | Intron (SNP) | VAF 5/39 reads (13%) | called by muse, mutect2, varscan2
- TPP1 | c.886+32G>A | Intron (SNP) | VAF 22/336 reads (7%) | called by muse, mutect2
- VPS11 | c.-589G>T | 5'UTR (SNP) | VAF 20/222 reads (9%) | called by muse, mutect2
- WNT16 | chr7:121325444 C>A | 5'Flank (SNP) | VAF 22/189 reads (12%) | catalogued as rs555476535; called by muse, mutect2, varscan2
- ZEB1 | c.58+44409G>T | Intron (SNP) | VAF 20/184 reads (11%) | catalogued as rs1353765574; called by muse, varscan2
- ZNF99 | c.*3092G>T | 3'UTR (SNP) | VAF 10/79 reads (13%) | catalogued as rs1022635374; called by muse, mutect2, varscan2
